Somatic mutation profile of tumor specimen TCGA-RW-A684-01A (aliquot TCGA-RW-A684-01A-12D-A35D-08) from TCGA case TCGA-RW-A684, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 64.2 years (23,440 days).
Specimen TCGA-RW-A684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77913165-e8ad-40c0-9f29-8cfbc9654d3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A684-10A (Blood Derived Normal), aliquot TCGA-RW-A684-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce8066dd-2656-417e-8c1f-e64e2bb7af13

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MICAL1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs867915353; called by muse, mutect2
- SCN10A | c.2225T>C p.L742P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV71860889; called by muse, mutect2, varscan2
- SPTA1 | c.7072G>A p.E2358K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1557917325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XDH | c.2681A>G p.N894S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs1466308175; called by muse, mutect2, varscan2
- ADH4 | c.988del p.S330Vfs*2 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.5291del p.N1764Tfs*3 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | called by mutect2, pindel, varscan2
- ZMYM1 | c.2014G>C p.A672P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- EMILIN3 | c.1332G>A p.G444= | Silent (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- FRMD4A | c.1284C>T p.P428= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- MAML1 | c.1101A>C p.S367= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- PPFIA2 | c.2139G>T p.L713= | Silent (SNP) | VAF 10/127 reads (8%) | catalogued as COSV61023461; called by muse, mutect2
- UGT2B4 | c.1569G>A p.K523= | Silent (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
